Somatic mutation profile of tumor specimen ALCH-ADUD-TTP1-A (aliquot ALCH-ADUD-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADUD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 60.8 years (22,204 days).
Specimen ALCH-ADUD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38de3759-4772-4712-b36b-2a32e8745487.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUD-NB1-A (Blood Derived Normal), aliquot ALCH-ADUD-NB1-C-2-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/844a7d8f-2203-4881-b2e4-4f65af42746e

The open-access MAF lists 949 somatic variants for this specimen: 665 protein-altering or splice-affecting, 168 silent, 116 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 572, Silent 168, Intron 56, Nonsense Mutation 51, RNA 18, Splice Site 16, 3'UTR 15, Frame Shift Del 12, 5'UTR 12, Splice Region 8, 5'Flank 8, 3'Flank 7.

Variants (750 of 949; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYGD | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 39/533 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs121909597, CM001976, COSV52205459; ClinVar: pathogenic; called by muse, mutect2
- SCN1A | c.1177C>A p.R393S | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121917929, CM066998, CM066999; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 47/439 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3349G>T p.E1117* | Nonsense Mutation (SNP) | VAF 71/630 reads (11%) | catalogued as COSV70039848; called by muse, mutect2, varscan2
- ABCG2 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as COSV52943040, COSV52948200; called by muse, mutect2, varscan2
- ADGB | c.1715C>A p.T572N | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1324600437; called by muse, varscan2
- ADGRF4 | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs143897106; called by muse, mutect2, varscan2
- AHNAK2 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs752703137; called by muse, mutect2, varscan2
- ANK2 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 25/385 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV52144257; called by muse, mutect2
- ANKEF1 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 55/435 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs149683797; called by muse, mutect2, varscan2
- ANKRD40 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV53332954; called by muse, mutect2
- ANO3 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | catalogued as COSV56781821; called by muse, mutect2, varscan2
- AP002512.3 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs560494144; called by muse, mutect2, varscan2
- AP3D1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.403); catalogued as rs758630548, COSV61425341; called by muse, mutect2
- APAF1 | c.1309T>A p.L437I (on ENST00000551964 / NM_181861.2; = p.L426I on NM_001160.3) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.695); catalogued as COSV59665320; called by muse, mutect2
- ARHGEF5 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 66/2136 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1276500620; called by muse, mutect2
- ARMC5 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772100424; called by muse, mutect2
- ASGR2 | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 16/358 reads (4%) | catalogued as COSV54691326; called by muse, mutect2
- ATF7IP | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99661287; called by muse, mutect2, varscan2
- ATP2B2 | c.2626G>T p.V876L (on ENST00000352432; = p.V842L on NM_001683.5) | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV59489698; called by muse, mutect2, varscan2
- ATP8A2 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681462; called by muse, mutect2
- AUTS2 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100715453; called by muse, mutect2, varscan2
- BTK | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as CM015174; called by muse, mutect2, varscan2
- C14orf119 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 22/496 reads (4%) | catalogued as rs995538514; called by muse, mutect2
- C20orf173 | c.141C>G p.C47W | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.742); catalogued as COSV55786267; called by muse, mutect2, varscan2
- C2orf16 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 34/656 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1300450927; called by muse, mutect2
- C8B | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100980714; called by muse, mutect2
- CACNG3 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV50064640; called by muse, mutect2, varscan2
- CAMKMT | c.965A>C p.H322P | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1166448157; called by muse, mutect2, varscan2
- CAND1 | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767306978; called by muse, mutect2, varscan2
- CASZ1 | c.4417C>A p.H1473N | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV100985816; called by muse, mutect2
- CCDC9 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 21/231 reads (9%) | catalogued as rs1024433069; called by muse, mutect2
- CD1E | c.64del p.Q22Rfs*8 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | catalogued as COSV63770647; called by mutect2, pindel, varscan2
- CDH9 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 12/270 reads (4%) | catalogued as rs1412302190, COSV50287076; called by muse, mutect2
- CHST1 | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV57324625; called by muse, mutect2, varscan2
- CIDEC | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 67/704 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1418902123; called by muse, mutect2
- CLASRP | c.1102G>T p.G368* | Nonsense Mutation (SNP) | VAF 14/125 reads (11%) | catalogued as rs1165819082; called by muse, mutect2, varscan2
- CLCN1 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 18/143 reads (13%) | catalogued as rs1032211764; called by muse, mutect2, varscan2
- CNGA4 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772497306, COSV101171815, COSV101171905; called by muse, mutect2, varscan2
- CNTN3 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1239838422; called by muse, mutect2
- CNTNAP5 | c.2693G>C p.R898T | Missense Mutation (SNP) | VAF 60/467 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs750201319; called by muse, mutect2, varscan2
- COG4 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs534448317; called by muse, mutect2, varscan2
- COL22A1 | c.3151G>T p.G1051C | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1176653953, COSV100276244; called by muse, mutect2, varscan2
- COL22A1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as rs1039597254; called by muse, mutect2
- COL4A5 | c.3223C>T p.L1075F | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs867632571; called by muse, mutect2, varscan2
- COL6A3 | c.3837C>A p.D1279E | Missense Mutation (SNP) | VAF 74/753 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs372089952, COSV55087116; ClinVar: uncertain significance; called by muse, mutect2
- CPE | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291536, COSV68579698; called by muse, mutect2
- CPT1C | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs576383638; called by muse, mutect2, varscan2
- CREB3L3 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 87/734 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50174399; called by muse, mutect2, varscan2
- CSMD1 | c.5584G>A p.G1862S (on ENST00000520002; = p.G1861S on NM_033225.6) | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59336054; called by muse, mutect2
- CST2 | c.229-2A>G p.X77_splice | Splice Site (SNP) | VAF 27/204 reads (13%) | catalogued as rs753506038; called by muse, mutect2, varscan2
- CYB5R2 | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs772801957; called by muse, mutect2
- CYP11B2 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 133/573 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59994448; called by muse, mutect2, varscan2
- DCN | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99271833; called by muse, mutect2
- DGKI | c.2498-6G>T | Splice Region (SNP) | VAF 55/506 reads (11%) | catalogued as rs762474967, COSV55940446; called by mutect2, varscan2
- DNAH6 | c.11122C>T p.L3708F | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52850436; called by muse, mutect2, varscan2
- DPP6 | c.7del p.E3Kfs*4 | Frame Shift Del (DEL) | VAF 28/271 reads (10%) | catalogued as rs1563207295; called by mutect2, pindel, varscan2
- DPYD | c.1700G>C p.G567A | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594664; called by muse, mutect2
- DROSHA | c.1031G>T p.W344L | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs1026615218; called by muse, mutect2, varscan2
- DST | c.2284G>A p.A762T (on ENST00000361203 / NM_001374722.1; = p.A436T on NM_001723.6) | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs766404235; called by muse, mutect2, varscan2
- ELN | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 53/529 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.763); catalogued as COSV99332883; called by muse, mutect2, varscan2
- ENPP2 | c.2478G>T p.R826S (on ENST00000075322 / NM_001040092.3; = p.R878S on NM_006209.5) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50014919; called by muse, mutect2
- EP300 | c.4228A>T p.R1410W | Missense Mutation (SNP) | VAF 124/613 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54333900; called by muse, varscan2
- EPB41L2 | c.1774G>C p.G592R | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV61356367; called by muse, mutect2, varscan2
- FAM135B | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52702200; called by muse, mutect2, varscan2
- FAM182A | n.1047-1G>T | Splice Site (SNP) | VAF 64/551 reads (12%) | catalogued as rs199617756; called by mutect2, varscan2
- FAT3 | c.12637C>A p.R4213S | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.229); catalogued as COSV53144188; called by muse, mutect2, varscan2
- FBN2 | c.3420C>A p.C1140* | Nonsense Mutation (SNP) | VAF 99/815 reads (12%) | catalogued as COSV52490627; called by muse, mutect2, varscan2
- FKBP3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV53531956; called by muse, mutect2
- FLG | c.7735G>C p.D2579H | Missense Mutation (SNP) | VAF 54/1042 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.849); catalogued as COSV64236980; called by muse, mutect2
- FLG | c.6359A>G p.D2120G | Missense Mutation (SNP) | VAF 86/665 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64239287, COSV64250945; called by muse, mutect2, varscan2
- FMN2 | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.063); catalogued as COSV60445353, COSV60459844, COSV99070473; called by muse, mutect2, varscan2
- FRMPD4 | c.2907C>G p.H969Q | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV66215306; called by muse, mutect2, varscan2
- FSIP2 | c.15869C>A p.S5290Y | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV58079443; called by muse, mutect2
- GDF9 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 77/550 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756289786; called by muse, mutect2, varscan2
- GPR78 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as COSV66763349; called by muse, mutect2, varscan2
- GRIP2 | c.2209G>T p.D737Y (on ENST00000619221; = p.D640Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56120506; called by muse, mutect2, varscan2
- GRK3 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs760791450; called by muse, mutect2, varscan2
- GTF3C1 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851244, COSV99852201; called by muse, mutect2
- GUCY2D | c.2767A>G p.K923E | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs745627220; called by muse, mutect2, varscan2
- HEATR5B | c.4057G>A p.A1353T | Missense Mutation (SNP) | VAF 67/555 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781367341, COSV51857666; called by muse, mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HTR1F | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60389477; called by muse, mutect2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 53/324 reads (16%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- JMJD1C | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1480443114; called by muse, mutect2
- KATNIP | c.582G>T p.R194S | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV55192119, COSV99850635; called by muse, varscan2
- KCNH1 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1417609305; called by muse, mutect2, varscan2
- KCNK9 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 100/1188 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV100271564; called by muse, mutect2
- KDM5A | c.2151A>G p.R717= | Splice Region (SNP) | VAF 42/162 reads (26%) | catalogued as rs1373458048; called by mutect2, varscan2
- KHDC3L | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 56/620 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as CD117059; called by muse, mutect2
- KIF6 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54676070; called by muse, mutect2
- KLHL6 | c.1693G>C p.G565R | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58064615; called by muse, mutect2, varscan2
- KLHL7 | c.881G>T p.R294L (on ENST00000339077 / NM_001031710.3; = p.R246L on NM_018846.5) | Missense Mutation (SNP) | VAF 86/607 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV59165446; called by muse, mutect2, varscan2
- KNL1 | c.2218G>T p.D740Y (on ENST00000346991 / NM_170589.5; = p.D714Y on NM_144508.5) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs1252140978; called by muse, mutect2, varscan2
- LAMA1 | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 20/770 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV101057244; called by muse, mutect2
- LAMA2 | c.2958G>T p.W986C | Missense Mutation (SNP) | VAF 60/626 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as CM151368, COSV70346121; called by muse, mutect2, varscan2
- LAMA3 | c.5707G>C p.E1903Q (on ENST00000313654 / NM_198129.4; = p.E294Q on NM_000227.6) | Missense Mutation (SNP) | VAF 26/648 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as COSV52539514; called by muse, mutect2
- LANCL2 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs755046284; called by muse, mutect2, varscan2
- LAP3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1412096693; called by muse, mutect2
- LATS1 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV53593815; called by muse, mutect2
- LBHD1 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs761768836, COSV100649029, COSV63473253; called by muse, mutect2
- LRFN2 | c.1818C>G p.N606K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV57831900; called by muse, mutect2, varscan2
- LRFN5 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 44/497 reads (9%) | catalogued as COSV53250975; called by muse, mutect2
- LRP1B | c.10658G>T p.C3553F | Missense Mutation (SNP) | VAF 61/478 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101251688; called by muse, mutect2, varscan2
- LRRC7 | c.128G>C p.R43P (on ENST00000651989 / NM_001370785.2; = p.R10P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50418241, COSV99230272; called by muse, mutect2, varscan2
- LRRC7 | c.3245C>A p.A1082D (on ENST00000651989 / NM_001370785.2; = p.A1049D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/498 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99224222; called by muse, mutect2, varscan2
- LRRIQ3 | c.338A>T p.K113M | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63050680; called by muse, mutect2, varscan2
- MANEA | c.520A>T p.R174* | Nonsense Mutation (SNP) | VAF 20/354 reads (6%) | catalogued as COSV100721541; called by muse, mutect2
- METTL21C | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57432727; called by muse, mutect2, varscan2
- MPP3 | c.144+1G>T p.X48_splice | Splice Site (SNP) | VAF 18/130 reads (14%) | catalogued as COSV68197709; called by muse, mutect2, varscan2
- MROH2B | c.1836G>A p.K612= | Splice Region (SNP) | VAF 19/340 reads (6%) | catalogued as rs1416000045; called by muse, mutect2
- MROH9 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100882719, COSV100882853; called by muse, mutect2
- MUC16 | c.33898G>T p.E11300* | Nonsense Mutation (SNP) | VAF 28/259 reads (11%) | catalogued as COSV67473555; called by muse, mutect2, varscan2
- MUC4 | c.9611C>T p.T3204I | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.517); catalogued as rs758692356; called by muse, varscan2
- MUC5B | c.12309C>G p.S4103R | Missense Mutation (SNP) | VAF 72/590 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs777702603; called by muse, mutect2, varscan2
- MYH6 | c.3836G>A p.R1279Q | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs200014711, COSV62448289; called by muse, mutect2
- MYLK2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 34/672 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV65659688; called by muse, mutect2
- NAPSA | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV53798477; called by muse, mutect2
- NAV3 | c.6382C>A p.L2128I (on ENST00000397909 / NM_001024383.2; = p.L2106I on NM_014903.6) | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV57098598; called by muse, mutect2
- NBAS | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 96/570 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372517600; called by muse, mutect2, varscan2
- NCAPG2 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 78/741 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99316739; called by muse, mutect2, varscan2
- NKX2-2 | c.741C>A p.Y247* | Nonsense Mutation (SNP) | VAF 28/182 reads (15%) | catalogued as rs1221836916, COSV101010604; called by muse, varscan2
- NOTCH4 | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs1253487294, COSV66679424, COSV66679988, COSV66681239; called by muse, mutect2
- NRIP1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59660009; called by muse, mutect2, varscan2
- ONECUT1 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.068); catalogued as rs1344737861; called by muse, mutect2, varscan2
- OR10V1 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV55696246; called by muse, mutect2, varscan2
- OR14A16 | c.839C>G p.P280R | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62926399; called by muse, mutect2, varscan2
- OR2G2 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374734951; called by mutect2, varscan2
- OR2G3 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as rs760469970, COSV60683221; called by muse, mutect2, varscan2
- OR2M4 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV60708101; called by muse, varscan2
- OR4D2 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 189/1529 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV73459754; called by muse, mutect2, varscan2
- OR4P4 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 15/198 reads (8%) | catalogued as COSV58921863; called by muse, mutect2
- OR5H15 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62948943; called by muse, mutect2, varscan2
- OR5K1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 49/508 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100220859; called by muse, mutect2, varscan2
- OR6P1 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as COSV58109376; called by muse, mutect2
- OR6Q1 | c.24G>C p.W8C | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56934470, COSV56935082; called by mutect2, varscan2
- PCDH11X | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV100008489, COSV53454550; called by muse, mutect2, varscan2
- PCDHA8 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65331812; called by muse, mutect2, varscan2
- PCDHGB4 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV53963523; called by muse, mutect2, varscan2
- PCK1 | c.955G>C p.A319P | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV60126288; called by muse, mutect2, varscan2
- PDZRN4 | c.2235C>A p.C745* (on ENST00000402685 / NM_001164595.2; = p.C487* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 31/396 reads (8%) | catalogued as COSV100115602, COSV54213720; called by muse, mutect2
- PIK3CG | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63248254; called by muse, mutect2, varscan2
- PKLR | c.644dup p.R216Pfs*5 | Frame Shift Ins (INS) | VAF 61/491 reads (12%) | catalogued as rs1557959906; called by mutect2, pindel, varscan2
- PLEKHS1 | c.784G>A p.E262K (on ENST00000369310 / NM_182601.1; = p.E268K on NM_024889.5) | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV63055093; called by muse, mutect2
- POLR3E | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs202036790, COSV99052122; called by mutect2, varscan2
- POTEG | c.219G>C p.R73S | Missense Mutation (SNP) | VAF 82/834 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV101611984; called by muse, mutect2, varscan2
- POU4F2 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 58/461 reads (13%) | catalogued as COSV55584183; called by muse, mutect2, varscan2
- PPIP5K2 | c.3089G>T p.W1030L | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.932); catalogued as COSV58606498; called by muse, mutect2
- PPP1R3A | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | catalogued as COSV99493087; called by muse, mutect2
- PRDM9 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 82/946 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1325974147, COSV57004034; called by muse, mutect2
- PREX2 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV55779029; called by muse, mutect2
- PROX1 | c.1441C>G p.R481G | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV54781441; called by muse, mutect2
- PRR5L | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1209690054; called by muse, mutect2
- PSG7 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV68445200; called by muse, mutect2
- PTCH1 | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 64/456 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs914090288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDNL | c.604G>C p.G202R | Missense Mutation (SNP) | VAF 41/466 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs772930795, COSV62485189; called by muse, mutect2
- RAPGEF2 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 100/635 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52425022; called by muse, mutect2, varscan2
- RFPL3 | c.214C>A p.H72N (on ENST00000249007 / NM_001098535.1; = p.H43N on NM_006604.2) | Missense Mutation (SNP) | VAF 161/687 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV99967167; called by muse, mutect2, varscan2
- RPL10L | c.614C>G p.P205R | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs768974320, COSV53560178; called by muse, mutect2
- RYR2 | c.12946G>C p.G4316R | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV63684982; called by muse, mutect2
- SALL1 | c.2332G>T p.A778S | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99177992; called by muse, mutect2
- SBF1 | c.1969-1G>A p.X657_splice | Splice Site (SNP) | VAF 10/204 reads (5%) | catalogued as COSV62369136; called by muse, mutect2
- SCAF8 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65793111; called by muse, mutect2, varscan2
- SENP7 | c.2762C>G p.S921W | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV58611179; called by muse, mutect2, varscan2
- SI | c.2608G>T p.G870* | Nonsense Mutation (SNP) | VAF 49/364 reads (13%) | catalogued as COSV52268877; called by muse, mutect2, varscan2
- SIGLEC1 | c.1353C>G p.I451M | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV52458563; called by muse, mutect2, varscan2
- SIGLEC1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as rs747739517; called by muse, mutect2, varscan2
- SLC25A42 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100588266; called by muse, varscan2
- SLC25A52 | c.863G>T p.R288L (on ENST00000672005; = p.R278L on NM_001034172.4) | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV52501761; called by muse, mutect2
- SLC8A1 | c.1979T>C p.V660A | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs762854301; called by muse, mutect2
- SMARCA4 | c.2438+1G>T p.X813_splice | Splice Site (SNP) | VAF 80/473 reads (17%) | catalogued as COSV60797108, COSV60809583; called by muse, mutect2, varscan2
- SORCS3 | c.1632C>A p.P544= | Splice Region (SNP) | VAF 32/423 reads (8%) | catalogued as rs367898736, COSV63810900; called by muse, mutect2
- SPDYE5 | c.952C>A p.R318S | Missense Mutation (SNP) | VAF 78/790 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.115); catalogued as rs782640592; called by muse, varscan2
- SPEF2 | c.4666G>C p.E1556Q | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.274); catalogued as COSV57429368; called by muse, mutect2
- SRR | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 87/594 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs373333825; called by muse, mutect2, varscan2
- SRRM2 | c.3071C>T p.S1024L | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1157988448; called by muse, mutect2, varscan2
- STRIP2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs986703724; called by muse, mutect2
- SUZ12 | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as rs769183880; called by mutect2, varscan2
- SVEP1 | c.10418G>A p.R3473Q | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.375); catalogued as rs370881734, COSV52841928; called by muse, mutect2, varscan2
- SYNE1 | c.20686C>T p.P6896S (on ENST00000367255 / NM_182961.4; = p.P6825S on NM_033071.3) | Missense Mutation (SNP) | VAF 72/621 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55021883; called by muse, mutect2, varscan2
- SYNE1 | c.11434G>T p.E3812* (on ENST00000367255 / NM_182961.4; = p.E3797* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 48/607 reads (8%) | catalogued as COSV55046946; called by muse, mutect2
- SYNGR2 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56745714; called by muse, mutect2, varscan2
- TAS2R30 | c.363A>G p.I121M | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs772480907; called by muse, mutect2
- TAS2R4 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV56093578; called by muse, mutect2, varscan2
- TAS2R41 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 37/396 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs780642693, COSV101281524; called by muse, mutect2
- TENM3 | c.5734C>A p.R1912S | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761419497, COSV69306896; called by muse, mutect2, varscan2
- TENM4 | c.4691G>A p.R1564Q | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.113); catalogued as rs771067289, COSV53647017; called by muse, mutect2, varscan2
- TLR4 | c.2209G>T p.V737L (on ENST00000355622 / NM_138554.5; = p.V697L on NM_003266.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100842685; called by muse, mutect2, varscan2
- TMEM100 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV70117926; called by muse, mutect2, varscan2
- TRHDE | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV53843861, COSV53846009; called by muse, mutect2
- TRIM58 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825306; called by muse, mutect2, varscan2
- TRIM67 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as rs573732801, COSV64158273; called by muse, mutect2, varscan2
- TSPYL5 | c.1183A>G p.K395E | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1255223349; called by muse, mutect2, varscan2
- TTN | c.8687C>A p.T2896N (on ENST00000591111; = p.T2850N on NM_003319.4) | Missense Mutation (SNP) | VAF 79/496 reads (16%) | PolyPhen probably damaging (0.997); catalogued as CM116748; called by muse, mutect2, varscan2
- TTYH1 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as COSV56611972; called by muse, mutect2, varscan2
- UBE2QL1 | c.40T>A p.F14I | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV67717122; called by muse, mutect2
- UNC93A | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs202230498, COSV57809938; called by muse, mutect2
- USH2A | c.6553C>A p.H2185N | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV56448944; called by muse, mutect2, varscan2
- USH2A | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 36/634 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV56332241, COSV56377571; called by muse, mutect2
- USP29 | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV99518167; called by muse, mutect2, varscan2
- VIM | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 82/695 reads (12%) | catalogued as COSV56408248; called by muse, mutect2, varscan2
- VLDLR | c.84del p.X28_splice | Splice Site (DEL) | VAF 41/352 reads (12%) | catalogued as COSV66074518; called by mutect2, pindel, varscan2
- VWA5B1 | c.3557C>G p.T1186R (on ENST00000375079; = p.T1181R on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs542391804, COSV99056021; called by muse, mutect2, varscan2
- WEE2 | c.724C>G p.R242G | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV66880035; called by muse, mutect2, varscan2
- ZFHX4 | c.4440C>A p.D1480E | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV50768184; called by muse, mutect2
- ZFP62 | c.187G>C p.E63Q (on ENST00000502412 / NM_001377944.1; = p.E30Q on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63092064; called by muse, mutect2, varscan2
- ZNF155 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV99525590; called by muse, mutect2
- ZNF445 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 30/543 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV101253772; called by muse, mutect2
- ZNF460 | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1339733182; called by muse, mutect2, varscan2
- ZNF521 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832457, COSV64122039; called by muse, mutect2
- ZNF536 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62832714; called by muse, mutect2, varscan2
- ZNF676 | c.751C>A p.H251N (on ENST00000650058; = p.H219N on NM_001001411.3) | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68094877; called by muse, varscan2
- ZNF728 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV74099310; called by muse, mutect2, varscan2
- ZNF728 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV74099032; called by muse, mutect2, varscan2
- ZNF804B | c.1793G>T p.S598I | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.212); catalogued as COSV60841395; called by muse, mutect2, varscan2
- ZNFX1 | c.4497C>G p.C1499W | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872149; called by muse, mutect2
- ABCB1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 87/883 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOD1 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, varscan2
- ACSM2B | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACVRL1 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 126/870 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ADAM32 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, varscan2
- ADAMTS16 | c.3053C>G p.P1018R | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.925); called by muse, mutect2
- ADCY2 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 103/485 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.118); called by muse, mutect2
- ADGRA2 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ADGRB3 | c.2273C>A p.S758Y | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- ADGRV1 | c.16439G>C p.S5480T | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.232); called by muse, varscan2
- AGAP9 | c.1444T>G p.C482G | Missense Mutation (SNP) | VAF 96/2249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ALDH1L1 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK2 | c.3148C>A p.Q1050K | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- ANGPTL5 | c.439+1G>T p.X147_splice | Splice Site (SNP) | VAF 76/548 reads (14%) | called by muse, mutect2, varscan2
- ANKRD36 | c.3727C>T p.L1243F | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- APEX1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2
- APOA2 | c.192C>G p.Y64* | Nonsense Mutation (SNP) | VAF 54/444 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.7A>T p.N3Y | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ARMC1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ASPH | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASS1 | c.977G>T p.W326L | Missense Mutation (SNP) | VAF 62/738 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASTN1 | c.1181G>C p.C394S | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ATAD2 | c.1612C>G p.P538A | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATP7B | c.2988G>C p.M996I | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AXIN2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 97/609 reads (16%) | called by muse, mutect2, varscan2
- BARD1 | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 43/444 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- BBX | c.2095A>T p.S699C | Missense Mutation (SNP) | VAF 76/723 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL11B | c.2353G>T p.G785W (on ENST00000357195 / NM_001282237.2; = p.G714W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEND4 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 59/654 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMP10 | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNC1 | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | called by muse, varscan2
- BPI | c.276C>A p.F92L (on ENST00000262865; = p.F88L on NM_001725.3) | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- BRWD3 | c.2830G>T p.D944Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C12orf40 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2
- C16orf78 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C19orf18 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- C1orf94 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CABS1 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADM1 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 90/948 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CARD11 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CASP10 | c.1376T>C p.I459T (on ENST00000272879 / NM_032974.5; = p.I416T on NM_001230.5) | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC166 | c.580dup p.A194Gfs*236 | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- CCDC168 | c.18802G>T p.E6268* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- CCDC178 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- CCDC197 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCT4 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD2AP | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 35/626 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); called by muse, mutect2
- CD300LB | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 67/408 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDC40 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- CDH22 | c.258C>A p.I86= | Splice Region (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- CDH23 | c.5887A>T p.T1963S | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH9 | c.2231A>C p.D744A | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- CEP295NL | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 91/714 reads (13%) | called by muse, mutect2, varscan2
- CFAP300 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CFAP54 | c.8741G>T p.C2914F | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP92 | c.3153T>G p.N1051K | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CHDH | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- CHMP4C | c.233A>C p.Q78P | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- CHRNA2 | c.576C>A p.F192L | Missense Mutation (SNP) | VAF 124/898 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCA1 | c.403A>C p.T135P | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLCN1 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 81/890 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2
- CLGN | c.1312C>G p.H438D | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- CMTM5 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 31/359 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- CNRIP1 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CNTN4 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 49/587 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- CNTNAP5 | c.2021G>T p.C674F | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A2 | c.2558G>T p.G853V (on ENST00000341947 / NM_080680.3; = p.G746V on NM_080679.2) | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A2 | c.2222A>T p.D741V (on ENST00000341947 / NM_080680.3; = p.D634V on NM_080679.2) | Missense Mutation (SNP) | VAF 84/902 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL2A1 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 64/574 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A3 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- COL6A5 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 48/610 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2
- CPED1 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CR1 | c.4858C>T p.Q1620* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- CRTC2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CSN3 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CSN3 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.095); called by muse, mutect2
- CUL4A | c.338A>T p.H113L (on ENST00000375440 / NM_001008895.4; = p.H13L on NM_003589.3) | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- CYP26A1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); called by muse, varscan2
- CYP7A1 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 92/898 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- DAPK1 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DAW1 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- DAW1 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- DCDC1 | c.5120G>T p.R1707I (on ENST00000597505 / NM_001367979.1; = p.R814I on NM_020869.3) | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DDC | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 58/723 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX52 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DEPDC5 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHCR7 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DKK2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 31/592 reads (5%) | called by muse, mutect2
- DLG3 | c.1964G>C p.C655S (on ENST00000374360 / NM_021120.4; = p.C350S on NM_020730.3) | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- DLGAP2 | c.1310G>T p.S437I | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- DLGAP3 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DMWD | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2
- DMXL2 | c.3050C>T p.T1017I | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- DNAH5 | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 33/821 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- DNAJB7 | c.449T>A p.F150Y | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DOCK2 | c.2220G>T p.L740F | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPRX | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 43/422 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSE | c.1035A>T p.Q345H | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.264); called by muse, mutect2
- DSG1 | c.2817G>C p.M939I | Missense Mutation (SNP) | VAF 47/864 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DSPP | c.2417G>A p.S806N | Missense Mutation (SNP) | VAF 151/1347 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DVL1 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDN3 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 50/656 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- EEF1AKNMT | c.982G>T p.A328S (on ENST00000361735 / NM_015935.5; = p.A242S on NM_014955.3) | Missense Mutation (SNP) | VAF 53/496 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- EFCAB6 | c.4120A>G p.K1374E | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- EFEMP1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 118/1132 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EIF4E1B | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- EIF5B | c.2659A>G p.T887A | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2
- EMILIN1 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- EML6 | c.4883G>A p.W1628* | Nonsense Mutation (SNP) | VAF 75/515 reads (15%) | called by muse, mutect2
- EML6 | c.4885G>A p.D1629N | Missense Mutation (SNP) | VAF 76/524 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- EPB41L1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 109/735 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EPHA5 | c.1353C>G p.S451R | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- EPHA6 | c.2758G>C p.D920H (on ENST00000389672 / NM_001080448.3; = p.D312H on NM_173655.4) | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS15 | c.1694A>G p.E565G | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); called by muse, mutect2
- ERCC3 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- ESPN | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETS2 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 48/990 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- EXOSC7 | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXTL3 | c.1660C>G p.P554A | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- EYA4 | c.1860C>A p.H620Q (on ENST00000531901 / NM_001301013.1; = p.H614Q on NM_004100.5) | Missense Mutation (SNP) | VAF 52/745 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2
- F5 | c.356A>T p.Y119F | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM169A | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAM177B | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 25/286 reads (9%) | called by muse, mutect2
- FAM89B | c.346del p.E116Sfs*13 (on ENST00000530349 / NM_001098785.2; = p.E103Sfs*13 on NM_152832.3) | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel
- FAT3 | c.5017C>G p.H1673D | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2
- FBLN7 | c.838del p.V280Cfs*29 | Frame Shift Del (DEL) | VAF 23/211 reads (11%) | called by mutect2, varscan2
- FCRL2 | c.1308-1G>T p.X436_splice | Splice Site (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- FN1 | c.6371C>A p.A2124D (on ENST00000359671 / NM_001365524.2; = p.A2093D on NM_002026.4) | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- FOXN4 | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- FPR2 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 112/543 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FRY | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 46/563 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.206); called by muse, mutect2
- FRY | c.8952G>A p.M2984I | Missense Mutation (SNP) | VAF 62/520 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCB | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 80/437 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FSIP2 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.306); called by muse, mutect2
- FSTL5 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GABRA6 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 78/548 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAD2 | c.487T>A p.C163S | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- GATD1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GBP3 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 72/1041 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GFI1 | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- GLG1 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 23/425 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2
- GLG1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 96/994 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2
- GLRB | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 46/407 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- GML | c.73T>A p.W25R | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPN3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GPR21 | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 54/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR4 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPR62 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.82); called by muse, mutect2
- GPR63 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 65/556 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- HCN1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 81/906 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2
- HDAC9 | c.2187A>T p.L729F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HEG1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- HERC2 | c.8333T>A p.L2778Q | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HMGCLL1 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- HOXA7 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.347); called by muse, mutect2
- HOXB3 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HOXC11 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HS6ST2 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- HSF2BP | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); called by muse, mutect2
- IGKV3D-11 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 157/1055 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV5-2 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV6D-41 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 47/700 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV6D-41 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 46/689 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- IMPDH1 | c.695A>T p.Y232F (on ENST00000470772 / NM_001142573.2; = p.Y318F on NM_000883.4) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2
- IPO8 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- IQCF5 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRAK3 | c.436+1G>C p.X146_splice | Splice Site (SNP) | VAF 13/232 reads (6%) | called by muse, mutect2
- ITGAD | c.2213A>C p.E738A | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.216); called by muse, mutect2
- JAK3 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.784); called by muse, varscan2
- KCND1 | c.1467G>T p.T489= | Splice Region (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2
- KCNS3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 69/479 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- KIAA1549L | c.2568G>T p.Q856H (on ENST00000321505; = p.Q1153H on NM_012194.3) | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIAA1549L | c.2569G>T p.A857S (on ENST00000321505; = p.A1154S on NM_012194.3) | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, varscan2
- KIF1B | c.910A>T p.I304F (on ENST00000377086 / NM_001365952.1; = p.I298F on NM_015074.3) | Missense Mutation (SNP) | VAF 69/492 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF27 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLHL40 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 30/273 reads (11%) | called by muse, mutect2, varscan2
- KPRP | c.1223T>A p.L408Q | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KYNU | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 64/566 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- L2HGDH | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.6657C>A p.Y2219* | Nonsense Mutation (SNP) | VAF 50/373 reads (13%) | called by muse, mutect2, varscan2
- LCT | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LOXHD1 | c.2307C>A p.S769R | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LRP2 | c.10609G>A p.D3537N | Missense Mutation (SNP) | VAF 85/586 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP8 | c.1874C>A p.T625N | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LURAP1L | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 68/566 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MAGEL2 | c.1146G>T p.W382C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MARK1 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MDC1 | c.6166G>T p.G2056W | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MEGF10 | c.3289G>T p.D1097Y | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MEIOC | c.2498C>A p.S833Y | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MIPEP | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MKRN3 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 70/475 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MPHOSPH10 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- MROH2B | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 96/936 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MRPS18A | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MSH2 | c.1904A>C p.K635T | Missense Mutation (SNP) | VAF 48/874 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- MTMR11 | c.508C>G p.Q170E (on ENST00000439741 / NM_001145862.2; = p.Q98E on NM_181873.3) | Missense Mutation (SNP) | VAF 28/764 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0.107); called by muse, mutect2
- MTMR2 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 41/814 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MTRES1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 98/602 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC12 | c.12827C>T p.T4276I (on ENST00000379442; = p.T4133I on NM_001164462.1) | Missense Mutation (SNP) | VAF 96/2031 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- MUC17 | c.2647A>T p.S883C | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MUC17 | c.5527A>G p.T1843A | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- MUC17 | c.9224G>T p.S3075I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MYH10 | c.4182G>C p.K1394N | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- MYH4 | c.1957G>C p.A653P | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- MYL10 | c.74T>C p.L25S | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO3A | c.821del p.K274Sfs*22 | Frame Shift Del (DEL) | VAF 75/721 reads (10%) | called by mutect2, pindel, varscan2
- MYOM2 | c.1465G>T p.V489F | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2
- MYRFL | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NAV2 | c.6922A>C p.N2308H (on ENST00000396087 / NM_001244963.2; = p.N2249H on NM_145117.5) | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, mutect2
- NAV3 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 65/506 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV3 | c.6383T>A p.L2128H (on ENST00000397909 / NM_001024383.2; = p.L2106H on NM_014903.6) | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NBAS | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 94/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBEA | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.5536G>T p.G1846W | Missense Mutation (SNP) | VAF 70/758 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2
- NBEAL2 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NBPF9 | c.278+1G>T p.X93_splice | Splice Site (SNP) | VAF 74/999 reads (7%) | called by muse, mutect2
- NCAPD2 | c.353A>T p.K118I | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCOA6 | c.2145G>T p.Q715H | Missense Mutation (SNP) | VAF 100/733 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NDST4 | c.1168del p.H390Tfs*6 | Frame Shift Del (DEL) | VAF 37/298 reads (12%) | called by mutect2, pindel, varscan2
- NECTIN4 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- NEPRO | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 33/223 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFATC2 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NIN | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- NINL | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIPBL | c.5692G>T p.D1898Y | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN1 | c.1271G>C p.G424A | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NLGN4X | c.1490T>C p.F497S | Missense Mutation (SNP) | VAF 55/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP3 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 144/1005 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NLRP4 | c.2284C>A p.Q762K | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH2 | c.3686G>C p.C1229S | Missense Mutation (SNP) | VAF 52/908 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPC1L1 | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 71/674 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- NPIPA5 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 36/1050 reads (3%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); called by muse, mutect2
- NR5A2 | c.713G>C p.S238T (on ENST00000367362 / NM_205860.3; = p.S192T on NM_003822.5) | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NTRK2 | c.2085dup p.G696Wfs*10 (on ENST00000323115 / NM_001369534.1; = p.G712Wfs*10 on NM_006180.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 49/430 reads (11%) | called by mutect2, pindel, varscan2
- NTSR1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODF1 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- OPA1 | c.72A>G p.I24M | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10A4 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2
- OR11G2 | c.988C>A p.L330I | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14K1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2
- OR2D3 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- OR2T1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- OR4D2 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 78/1428 reads (5%) | called by muse, mutect2
- OR4P4 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- OR51B5 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- OR51B5 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52R1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR56A4 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2
- OR5D14 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2
- OR5P3 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 48/458 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR6A2 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR6X1 | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR8K5 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OSBPL9 | c.498G>C p.M166I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OTOGL | c.5240G>T p.R1747I (on ENST00000547103; = p.R1738I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- P4HA3 | c.1328A>T p.H443L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2
- PAGE2 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAK5 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 84/796 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAM | c.2485+1G>T p.X829_splice | Splice Site (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2, varscan2
- PARS2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH11Y | c.1282del p.V428* (on ENST00000400457 / NM_032973.2; = p.V417* on NM_032971.3) | Frame Shift Del (DEL) | VAF 79/427 reads (19%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA1 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 69/469 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PCDHGA3 | c.2324A>C p.Y775S | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHGA9 | c.2338A>C p.I780L | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGB2 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2
- PCNT | c.5060A>G p.N1687S | Missense Mutation (SNP) | VAF 102/903 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDZD8 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PEAR1 | c.2774A>T p.Y925F | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PEG3 | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, varscan2
- PEG3 | c.3453C>A p.S1151R | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, varscan2
- PGLYRP2 | c.1082T>A p.L361Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- PIP4P2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.178); called by muse, mutect2
- PIWIL1 | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIWIL4 | c.1067T>A p.L356H | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKHD1L1 | c.5807G>T p.G1936V | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLCH1 | c.4290A>T p.Q1430H (on ENST00000340059 / NM_001130960.2; = p.Q1422H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/532 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA5 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA1 | c.4076G>T p.G1359V | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- POGK | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- POM121L12 | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPFIA4 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 54/453 reads (12%) | called by muse, mutect2, varscan2
- PPP1R21 | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 103/863 reads (12%) | called by muse, mutect2, varscan2
- PPP1R2B | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 74/588 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, varscan2
- PPP1R3A | c.900T>A p.S300R | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- PPP2R5A | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRAG1 | c.3587C>T p.A1196V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.234); called by muse, varscan2
- PRAMEF15 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 39/899 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2
- PREX2 | c.4372T>A p.S1458T | Missense Mutation (SNP) | VAF 42/457 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- PRICKLE2 | c.925G>C p.E309Q (on ENST00000295902; = p.E253Q on NM_198859.4) | Missense Mutation (SNP) | VAF 59/538 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, varscan2
- PRKAA2 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRODH2 | c.1196C>A p.P399H (on ENST00000301175; = p.P323H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRR32 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PRRT3 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PSMC6 | c.115C>T p.R39C (on ENST00000612399; = p.R25C on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTPN1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 96/722 reads (13%) | called by muse, mutect2, varscan2
- PTPN20 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 46/1116 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- PTPRN | c.413del p.G138Efs*62 | Frame Shift Del (DEL) | VAF 36/335 reads (11%) | called by mutect2, pindel, varscan2
- PZP | c.4165G>T p.V1389L | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RAB3IP | c.456del p.L153* (on ENST00000550536 / NM_175623.4; = p.L137* on NM_022456.5) | Frame Shift Del (DEL) | VAF 50/425 reads (12%) | called by mutect2, pindel, varscan2
- RAB4A | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RABGGTB | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- RAET1L | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 62/1073 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2
- RALYL | c.458T>A p.V153E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- RASAL2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- RBM24 | c.261C>A p.Y87* (on ENST00000379052 / NM_001143942.2; = p.Y42* on NM_153020.2) | Nonsense Mutation (SNP) | VAF 59/282 reads (21%) | called by muse, varscan2
- RBMXL3 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- RECQL | c.469T>A p.S157T | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- REG3G | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RFC3 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 41/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RFPL4A | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 119/999 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RHEB | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2
- RNF182 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 64/563 reads (11%) | called by muse, mutect2, varscan2
- ROS1 | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); called by muse, mutect2
- RSBN1L | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.836); called by muse, varscan2
- RTL1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RTL4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RUNX1T1 | c.613C>G p.Q205E (on ENST00000265814 / NM_001198628.1; = p.Q178E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SCEL | c.1160G>C p.G387A (on ENST00000349847 / NM_144777.3; = p.G367A on NM_003843.4) | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.861); called by muse, varscan2
- SCGB1D1 | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 48/359 reads (13%) | called by muse, mutect2, varscan2
- SDAD1 | c.338T>A p.I113N | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- SDK2 | c.6G>A p.W2* | Nonsense Mutation (SNP) | VAF 38/245 reads (16%) | called by muse, mutect2, varscan2
- SFTPB | c.857-4C>T | Splice Region (SNP) | VAF 32/723 reads (4%) | called by muse, mutect2
- SH3GLB2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2
- SHANK3 | c.2534G>C p.R845P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- SHROOM3 | c.2157G>C p.Q719H | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- SHROOM3 | c.5896G>A p.A1966T | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIPA1L1 | c.248G>C p.W83S | Missense Mutation (SNP) | VAF 109/702 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SIRPG | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 62/634 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.768); called by muse, mutect2
- SKIL | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SLC13A2 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); called by muse, mutect2
- SLC17A7 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC2A11 | c.380G>A p.G127E (on ENST00000345044 / NM_001024938.4; = p.G134E on NM_030807.5) | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC2A4 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC30A9 | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2, varscan2
- SLC38A6 | c.362A>T p.K121M | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC39A7 | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SLC8A3 | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC9A9 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 41/495 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- SLCO1A2 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX5 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2
- SOS1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 36/838 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SOX1 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SP5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SP8 | c.182G>T p.R61M (on ENST00000361443 / NM_198956.4; = p.R79M on NM_182700.6) | Missense Mutation (SNP) | VAF 80/566 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- SPATA13 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 28/388 reads (7%) | called by muse, mutect2
- SPATA18 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPATA31A6 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 59/678 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SPATA5L1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPECC1L | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 142/778 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEF2 | c.3704T>A p.M1235K | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.01); called by muse, mutect2
- SPINK5 | c.2092G>T p.G698C | Missense Mutation (SNP) | VAF 47/377 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SPOCD1 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTA1 | c.3530A>T p.Q1177L | Missense Mutation (SNP) | VAF 34/393 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- SRPRB | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- SRSF4 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2
- ST14 | c.1515C>G p.F505L | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2
- ST18 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 55/455 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STS | c.568del p.V190Sfs*19 | Frame Shift Del (DEL) | VAF 57/326 reads (17%) | called by mutect2, pindel, varscan2
- SUN5 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TAGAP | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 63/550 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R4 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2
- TBC1D32 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 44/424 reads (10%) | called by muse, mutect2, varscan2
- TCFL5 | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDO2 | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2
- TDP2 | c.978G>C p.E326D | Missense Mutation (SNP) | VAF 92/632 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD5 | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 105/785 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM3 | c.2004C>A p.D668E | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TFEB | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2
- TFEC | c.866T>A p.F289Y | Missense Mutation (SNP) | VAF 17/279 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- THSD7B | c.3761G>A p.G1254E (on ENST00000272643; = p.G1252E on NM_001316349.2) | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TIGD5 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TIMELESS | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 49/418 reads (12%) | called by muse, mutect2, varscan2
- TLR6 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- TMEM117 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TMEM132E | c.326del p.Q109Rfs*12 | Frame Shift Del (DEL) | VAF 49/286 reads (17%) | called by mutect2, pindel, varscan2
- TMEM71 | c.836A>G p.H279R | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TMPRSS15 | c.1565-1G>A p.X522_splice | Splice Site (SNP) | VAF 24/554 reads (4%) | called by muse, mutect2
- TNRC6B | c.2311G>T p.G771W | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TOP1MT | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- TRHDE | c.1009dup p.C337Lfs*23 | Frame Shift Ins (INS) | VAF 36/287 reads (13%) | called by mutect2, pindel, varscan2
- TRIM10 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 54/556 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TRIM49 | c.361C>G p.H121D | Missense Mutation (SNP) | VAF 43/435 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM49B | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2
- TRIM55 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 67/614 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIP13 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 34/745 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM7 | c.4642G>T p.A1548S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, varscan2
- TRPS1 | c.2677G>T p.G893C (on ENST00000220888 / NM_001330599.2; = p.G906C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/861 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSHZ3 | c.2758G>T p.G920W | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.77794C>A p.P25932T (on ENST00000591111; = p.P18508T on NM_003319.4) | Missense Mutation (SNP) | VAF 59/441 reads (13%) | PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TTN | c.59230T>A p.L19744I (on ENST00000591111; = p.L12320I on NM_003319.4) | Missense Mutation (SNP) | VAF 75/650 reads (12%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.29301A>G p.I9767M (on ENST00000591111; = p.I8840M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/204 reads (4%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.7069G>T p.A2357S (on ENST00000591111; = p.A2311S on NM_003319.4) | Missense Mutation (SNP) | VAF 38/295 reads (13%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBA3C | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TUBA3C | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TXNRD3 | c.520-1G>A p.X174_splice | Splice Site (SNP) | VAF 43/306 reads (14%) | called by muse, mutect2, varscan2
- UBOX5 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 48/604 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- UHRF1BP1L | c.702A>T p.L234F | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13C | c.3128C>A p.T1043N | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.11); called by muse, varscan2
- UNC13C | c.6340T>A p.Y2114N | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UNC80 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2
- UNC80 | c.7227G>T p.Q2409H | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- UPF2 | c.2890A>G p.K964E | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- USH2A | c.7043G>T p.R2348M | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- USH2A | c.3811+1G>T p.X1271_splice | Splice Site (SNP) | VAF 40/470 reads (9%) | called by muse, mutect2
- USP2 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- USP53 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); called by muse, mutect2
- VAMP7 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 27/401 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2
- VARS2 | c.2729T>C p.V910A | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- VIM | c.1008+3G>T | Splice Region (SNP) | VAF 84/831 reads (10%) | called by muse, mutect2
- VRTN | c.1308T>A p.Y436* | Nonsense Mutation (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- VTI1B | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- WDHD1 | c.2726G>T p.G909V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2
- WDR17 | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, varscan2
- WDR17 | c.2959G>T p.E987* | Nonsense Mutation (SNP) | VAF 40/535 reads (7%) | called by muse, mutect2
- WDR46 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- WDR97 | c.3733G>C p.G1245R | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- WFS1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- WIPI1 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- WNT9B | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- XCR1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- XRN2 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 56/446 reads (13%) | called by muse, varscan2
- YTHDC1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 30/576 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2
- ZBTB17 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB39 | c.1321G>T p.G441C | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZFHX4 | c.5357A>G p.H1786R | Missense Mutation (SNP) | VAF 49/419 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZFHX4 | c.8197C>A p.P2733T | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1830G>C p.E610D | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF185 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZNF335 | c.2441A>G p.Q814R | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF418 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); called by muse, mutect2
- ZNF460 | c.1125C>A p.H375Q | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF468 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.227); called by muse, mutect2
- ZNF469 | c.7738G>A p.E2580K (on ENST00000437464; = p.E2608K on NM_001367624.2) | Missense Mutation (SNP) | VAF 90/748 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.343); called by muse, varscan2
- ZNF521 | c.384C>G p.S128R | Missense Mutation (SNP) | VAF 49/506 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2
- ZNF568 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ZNF676 | c.1823T>A p.V608D (on ENST00000650058; = p.V576D on NM_001001411.3) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF679 | c.651C>G p.C217W | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF717 | c.1660C>A p.H554N | Missense Mutation (SNP) | VAF 45/554 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2
- ZNF738 | c.333G>T p.L111F | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF800 | c.182T>C p.L61S | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF804A | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- ZNF844 | c.1119G>T p.L373F | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNRF3 | c.2164G>T p.G722W (on ENST00000544604 / NM_001206998.2; = p.G622W on NM_032173.3) | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZP4 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ZSCAN5C | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- ZSCAN5C | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2
- AC100868.1 | c.780C>A p.T260= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- ACMSD | c.417C>A p.P139= | Silent (SNP) | VAF 62/678 reads (9%) | catalogued as COSV51605624; called by muse, mutect2
- ADAMTS20 | c.3390A>G p.V1130= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- ADGRV1 | c.4182G>A p.V1394= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as rs1356296605; called by muse, mutect2, varscan2
- AJM1 | c.2076C>T p.Y692= | Silent (SNP) | VAF 15/198 reads (8%) | catalogued as rs1317192077; called by muse, mutect2
- AKR1B10 | c.648G>T p.P216= | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as COSV100610212; called by muse, mutect2, varscan2
- AMZ1 | c.531C>T p.G177= | Silent (SNP) | VAF 57/511 reads (11%) | called by muse, mutect2, varscan2
- ANKRD24 | c.1344G>T p.V448= | Silent (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.237G>C p.L79= | Silent (SNP) | VAF 104/744 reads (14%) | called by muse, mutect2, varscan2
- ARMC3 | c.1905A>G p.R635= | Silent (SNP) | VAF 39/332 reads (12%) | called by muse, mutect2, varscan2
- ARMCX2 | c.1332T>C p.I444= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs1556052391; called by muse, varscan2
- ASCL1 | c.378C>G p.R126= | Silent (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- ATP1A3 | c.387T>A p.S129= (on ENST00000545399 / NM_001256214.2; = p.S116= on NM_152296.5) | Silent (SNP) | VAF 53/497 reads (11%) | called by muse, mutect2, varscan2
- ATR | c.2715A>T p.G905= | Silent (SNP) | VAF 46/387 reads (12%) | called by muse, mutect2, varscan2
- BABAM2 | c.603C>T p.A201= | Silent (SNP) | VAF 43/308 reads (14%) | catalogued as rs1194154152, COSV59622040; called by muse, mutect2, varscan2
- BAIAP3 | c.1158G>C p.L386= | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- BMS1 | c.3024A>C p.I1008= | Silent (SNP) | VAF 53/435 reads (12%) | called by muse, mutect2, varscan2
- BPNT1 | c.303A>G p.P101= | Silent (SNP) | VAF 56/479 reads (12%) | catalogued as rs1227141089; called by muse, mutect2, varscan2
- C19orf47 | c.495C>T p.S165= | Silent (SNP) | VAF 49/373 reads (13%) | called by muse, mutect2, varscan2
- C1QB | c.132A>G p.T44= | Silent (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- CALN1 | c.24C>A p.A8= (on ENST00000329008 / NM_001017440.3; = p.A50= on NM_031468.4) | Silent (SNP) | VAF 54/407 reads (13%) | called by muse, mutect2, varscan2
- CAPN14 | c.1410G>A p.T470= | Silent (SNP) | VAF 108/967 reads (11%) | catalogued as rs999285869; called by muse, mutect2, varscan2
- CDHR1 | c.984G>C p.A328= | Silent (SNP) | VAF 53/378 reads (14%) | called by muse, mutect2, varscan2
- CENPC | c.2529A>G p.P843= | Silent (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2
- CLU | c.1155G>C p.R385= | Silent (SNP) | VAF 36/412 reads (9%) | called by muse, mutect2
- CLVS2 | c.36C>A p.T12= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2
- CNTLN | c.1578A>G p.E526= | Silent (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- COL14A1 | c.3084G>T p.A1028= | Silent (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- COL5A2 | c.3795C>T p.D1265= | Silent (SNP) | VAF 87/1132 reads (8%) | called by muse, mutect2
- CPS1 | c.4389C>A p.L1463= | Silent (SNP) | VAF 37/470 reads (8%) | catalogued as rs1433915902; called by muse, mutect2
- CRACD | c.2388G>T p.P796= | Silent (SNP) | VAF 66/542 reads (12%) | catalogued as COSV51728659; called by muse, mutect2, varscan2
- CYP11B2 | c.225G>T p.L75= | Silent (SNP) | VAF 114/472 reads (24%) | called by muse, mutect2, varscan2
- CYP4F11 | c.64C>T p.L22= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- CYP7B1 | c.180G>A p.L60= | Silent (SNP) | VAF 26/722 reads (4%) | catalogued as COSV59598340; called by muse, mutect2
- DNAH12 | c.1773T>C p.D591= | Silent (SNP) | VAF 48/328 reads (15%) | catalogued as rs573460807; called by muse, mutect2, varscan2
- DUOX2 | c.4482C>T p.P1494= | Silent (SNP) | VAF 57/340 reads (17%) | catalogued as rs1228427422; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.675G>T p.A225= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- EFCAB2 | c.177C>T p.S59= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1469837211; called by muse, mutect2
- EPC1 | c.2109A>T p.T703= | Silent (SNP) | VAF 34/247 reads (14%) | called by muse, varscan2
- FAM124A | c.996G>C p.R332= (on ENST00000322475 / NM_001242312.2; = p.R368= on NM_145019.4) | Silent (SNP) | VAF 24/265 reads (9%) | catalogued as COSV54480067; called by muse, mutect2, varscan2
- FASLG | c.216G>A p.K72= | Silent (SNP) | VAF 42/425 reads (10%) | catalogued as COSV60681204; called by muse, mutect2, varscan2
- FER1L5 | c.3006C>A p.P1002= (on ENST00000623019; = p.P1009= on NM_001293083.2) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1163628347; called by muse, mutect2, varscan2
- FOXH1 | c.463C>A p.R155= | Silent (SNP) | VAF 63/315 reads (20%) | called by muse, mutect2, varscan2
- FTHL17 | c.231C>A p.R77= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV100784463; called by muse, mutect2, varscan2
- GALM | c.366G>T p.V122= | Silent (SNP) | VAF 108/609 reads (18%) | catalogued as rs1290022266; called by muse, mutect2, varscan2
- GLG1 | c.822G>T p.L274= | Silent (SNP) | VAF 94/988 reads (10%) | called by muse, mutect2
- GPC6 | c.243C>G p.L81= | Silent (SNP) | VAF 26/517 reads (5%) | catalogued as COSV65527332; called by muse, mutect2
- GSDMA | c.492A>G p.T164= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- GSG1L2 | c.504G>C p.V168= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, varscan2
- HBB | c.105C>A p.V35= | Silent (SNP) | VAF 84/814 reads (10%) | called by muse, mutect2, varscan2
- HRH1 | c.357C>T p.F119= | Silent (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- HRNR | c.7098C>T p.S2366= | Silent (SNP) | VAF 128/4774 reads (3%) | called by muse, mutect2
- HSCB | c.264G>A p.A88= | Silent (SNP) | VAF 46/632 reads (7%) | catalogued as rs187513400, COSV53262483; called by muse, mutect2
- IDO2 | c.1095G>T p.G365= (on ENST00000389060; = p.G378= on NM_194294.2) | Silent (SNP) | VAF 50/458 reads (11%) | called by muse, mutect2, varscan2
- IL13RA2 | c.165C>A p.P55= | Silent (SNP) | VAF 53/175 reads (30%) | catalogued as COSV54567022; called by muse, mutect2, varscan2
- INCENP | c.906G>T p.S302= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as rs776360227; called by muse, mutect2, varscan2
- ITGAD | c.2142G>T p.L714= | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as rs760362020; called by muse, mutect2, varscan2
- IZUMO3 | c.159G>T p.R53= | Silent (SNP) | VAF 42/432 reads (10%) | called by muse, mutect2
- KCNK18 | c.102C>A p.A34= | Silent (SNP) | VAF 99/630 reads (16%) | called by muse, mutect2, varscan2
- KCNK9 | c.723G>T p.L241= | Silent (SNP) | VAF 84/409 reads (21%) | called by muse, mutect2, varscan2
- KCNT1 | c.2313T>C p.Y771= (on ENST00000488444; = p.Y790= on NM_020822.3) | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2
- KIAA1549L | c.2550C>T p.I850= (on ENST00000321505; = p.I1147= on NM_012194.3) | Silent (SNP) | VAF 32/293 reads (11%) | catalogued as rs768110250, COSV55776380; called by muse, varscan2
- KRT31 | c.303C>A p.P101= | Silent (SNP) | VAF 32/316 reads (10%) | called by muse, varscan2
- LGALS3BP | c.1695C>T p.H565= | Silent (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- LILRB5 | c.1389G>T p.G463= (on ENST00000449561 / NM_001081442.3; = p.G462= on NM_006840.5) | Silent (SNP) | VAF 22/307 reads (7%) | called by muse, mutect2
- LOXL1 | c.273C>T p.S91= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- LPIN1 | c.105G>A p.G35= | Silent (SNP) | VAF 58/498 reads (12%) | catalogued as rs568680579, COSV71938403; called by muse, mutect2, varscan2
- LRRC7 | c.129G>T p.R43= (on ENST00000651989 / NM_001370785.2; = p.R10= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as COSV50428674; called by muse, mutect2, varscan2
- LRRC7 | c.1530T>C p.N510= (on ENST00000651989 / NM_001370785.2; = p.N477= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1371C>A p.L457= | Silent (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- MAB21L3 | c.852G>T p.L284= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- MALRD1 | c.6321C>A p.T2107= | Silent (SNP) | VAF 75/482 reads (16%) | called by muse, mutect2, varscan2
- MGME1 | c.585G>A p.E195= | Silent (SNP) | VAF 32/1122 reads (3%) | called by muse, mutect2
- MKI67 | c.87T>C p.F29= | Silent (SNP) | VAF 67/529 reads (13%) | called by muse, mutect2, varscan2
- MMD2 | c.690G>T p.G230= (on ENST00000404774 / NM_001100600.2; = p.G206= on NM_198403.4) | Silent (SNP) | VAF 68/736 reads (9%) | catalogued as COSV101287022; called by muse, mutect2
- MMS22L | c.2742G>A p.K914= | Silent (SNP) | VAF 58/558 reads (10%) | called by muse, mutect2, varscan2
- MSX2 | c.231G>T p.R77= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as rs759346366; called by muse, mutect2, varscan2
- MTUS2 | c.3831C>T p.I1277= (on ENST00000612955 / NM_001366650.1; = p.I256= on NM_015233.6) | Silent (SNP) | VAF 46/387 reads (12%) | catalogued as COSV66420750; called by muse, mutect2, varscan2
- MYBPC1 | c.1482C>T p.L494= (on ENST00000550270 / NM_206820.2; = p.L519= on NM_002465.4) | Silent (SNP) | VAF 24/497 reads (5%) | called by muse, mutect2
- MYO18A | c.384C>T p.A128= | Silent (SNP) | VAF 47/395 reads (12%) | called by muse, mutect2, varscan2
- NBAS | c.2256G>C p.L752= | Silent (SNP) | VAF 99/704 reads (14%) | catalogued as rs561346166; called by muse, mutect2, varscan2
- NCAPD2 | c.3642C>T p.F1214= | Silent (SNP) | VAF 11/245 reads (4%) | catalogued as COSV57520434; called by muse, mutect2
- NLRP7 | c.1152C>A p.V384= | Silent (SNP) | VAF 55/445 reads (12%) | called by muse, mutect2, varscan2
- NPAS3 | c.72G>T p.L24= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as COSV58072465; called by muse, mutect2
- NRK | c.4624C>T p.L1542= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
199 further variants in this file (0 protein-altering or splice-affecting, 83 silent, 116 other) are not listed here.
